Gene-level copy-number profile of tumor specimen TCGA-13-0888-01A from TCGA case TCGA-13-0888, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 78.0 years (28,498 days).
Specimen TCGA-13-0888-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e60603fe-0486-4ab6-8ae2-de80564bd5f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0888-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/40f10b7a-7cea-41cd-9b8a-61266f51efff

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 2,608; copy number 2: 4,048; copy number 3: 24,368; copy number 4: 12,519; copy number 5: 11,584; copy number 6: 2,162; copy number 7: 1,151; copy number 8: 170; copy number 9: 190; copy number 10: 12; copy number 11: 85; copy number 12: 195; copy number 13: 187; copy number 14: 17; copy number 15: 172; copy number 16: 2; copy number 17: 97; copy number 18: 137; copy number 20: 23; copy number 21: 2; copy number 25: 6; copy number 33: 28; copy number 35: 16; copy number 44: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0888-01A-01D-0399-01): tumor purity 0.79, ploidy 3.8, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,479 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:183,248,237–185,657,168, 53 genes, copy number 18: NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1, SMG7, NCF2, AL137800.1, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1, COLGALT2, TSEN15, AL158011.1, Y_RNA, Y_RNA, AL445228.1, RN7SL654P, AL445228.2, C1orf21, AL078645.1, AL078645.2, AL713852.1, AL713852.2, EDEM3, NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1.
- chr1:188,013,642–188,888,540, 10 genes, copy number 25–44: AL136372.2, AL136372.1, RN7SKP156, AL596211.1, AL592447.1, AL929288.1, AL929288.2, RPS3AP9, AL691515.1, AL691515.2.
- chr1:189,666,149–190,801,658, 11 genes, copy number 7 (within-gene range 4–7): RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720, AL139135.1.
- chr1:223,091,872–223,188,154, 4 genes, copy number 14: AL929091.1, TLR5, AL359979.2, AL359979.1.
- chr1:224,107,282–229,508,341, 176 genes, copy number 7–15 (within-gene range 6–15) (broad region; genes not listed).
- chr1:233,904,676–236,764,631, 84 genes, copy number 13–18 (within-gene range 4–18) (broad region; genes not listed).
- chr3:163,455,568–198,222,513, 640 genes, copy number 7–8 (broad region; genes not listed).
- chr4:51,843,000–56,033,361, 83 genes, copy number 7 (broad region; genes not listed).
- chr4:56,097,390–56,097,504, 1 gene, copy number 7: RNA5SP161.
- chr4:65,669,961–66,431,521, 10 genes, copy number 8: EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1, AC110809.1, MIR1269A, RPS23P3.
- chr6:29,464,596–29,752,207, 28 genes, copy number 33: UBDP1, MAS1LP1, MAS1L, RPS17P1, LINC02829, LINC01015, GPR53P, OR2I1P, UBD, GABBR1, OR2H5P, TMEM183AP1, SNORD32B, RPL13AP, OR2H2, SUMO2P1, MOG, ZFP57, ZDHHC20P1, HLA-F, AL645939.1, HLA-F-AS1, RPL23AP1, MICE, AL645939.2, Y_RNA, IFITM4P, AL645939.4.
- chr6:33,131,216–33,746,905, 46 genes, copy number 12: HLA-DPA3, HCG24, COL11A2, RXRB, RNY4P10, SLC39A7, HSD17B8, MIR219A1, RING1, ZNF70P1, HTATSF1P1, AL645940.1, HCG25, VPS52, RPS18, B3GALT4, WDR46, MIR6873, PFDN6, MIR6834, RGL2, TAPBP, ZBTB22, DAXX, SMIM40, SMIM40, MYL8P, LYPLA2P1, RPL35AP4, KIFC1, RPL12P1, PHF1, CUTA, SYNGAP1, SYNGAP1-AS1, MIR5004, ZBTB9, GGNBP1, RN7SL26P, Metazoa_SRP, BAK1, LINC00336, ITPR3, UQCC2, MIR3934, IP6K3.
- chr6:36,354,091–53,617,171, 381 genes, copy number 11–18 (within-gene range 3–18) (broad region; genes not listed).
- chr6:56,331,788–57,222,307, 15 genes, copy number 9: AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23.
- chr8:37,736,601–39,860,525, 60 genes, copy number 12: ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2.
- chr8:55,067,585–56,993,867, 37 genes, copy number 8: AC084834.1, XKR4, AC022679.2, AC022679.1, SBF1P1, AC090200.1, TMEM68, RNA5SP265, TGS1, LYN, AC018607.1, SNORA1B, RN7SL798P, RN7SL323P, AC046176.1, RPS20, SNORD54, CERNA3, NPM1P21, MOS, AC107376.1, PLAG1, CHCHD7, AC107952.2, AC107952.1, SDR16C5, SDR16C6P, PENK, AC012349.1, SEPTIN10P1, LINC00968, AC013644.1, RPL37P6, AC009597.1, AC009597.2, RNU6-13P, BPNT2.
- chr10:46,033,307–46,131,358, 3 genes, copy number 14: MSMB, RPL23AP61, AGAP7P.
- chr10:46,337,224–48,672,424, 63 genes, copy number 7–21 (broad region; genes not listed).
- chr11:63,046,785–64,532,970, 72 genes, copy number 7 (broad region; genes not listed).
- chr12:17,383,352–25,814,171, 116 genes, copy number 7–8 (broad region; genes not listed).
- chr12:31,948,334–38,087,392, 51 genes, copy number 7: RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2, Y_RNA, FGD4, RNU6-494P, DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2, PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1, ZNF970P, AK6P2, CLUHP8.
- chr12:50,842,920–50,887,884, 1 gene, copy number 8 (within-gene range 6–8): TMPRSS12.
- chr12:50,923,472–52,252,186, 52 genes, copy number 8 (within-gene range 3–8): METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P, POU6F1, AC139768.1, DAZAP2, SMAGP, BIN2, CELA1, GALNT6, SLC4A8, AC107031.1, SCN8A, HNRNPA3P10, AC068987.1, TMDD1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1, ACVR1B, RNU6-574P, TAMALIN, NR4A1, NR4A1AS, ATG101, AC025259.1, SMIM41, OR7E47P, AC078864.1, LINC00592, KRT80, LINC02874, METTL7AP1, KRT7, KRT7-AS.
- chr12:53,935,328–55,030,017, 64 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr12:56,285,916–58,395,138, 111 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr12:60,092,864–61,232,937, 7 genes, copy number 7: AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2, AC090017.1.
- chr12:63,055,275–71,118,247, 179 genes, copy number 11–35 (within-gene range 3–35) (broad region; genes not listed).
- chr12:119,283,825–122,527,000, 121 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 578. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
